Somatic mutation profile of tumor specimen C3L-02357-02 (aliquot CPT0113330009) from CPTAC case C3L-02357, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G2; Age at diagnosis: 54.1 years (19,771 days).
Specimen C3L-02357-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0888daf1-0e90-4f04-859f-c99ed00071f8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02357-31 (Blood Derived Normal), aliquot CPT0115280002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0f626539-8c7b-4562-bc9f-5399378bcea1

The open-access MAF lists 122 somatic variants for this specimen: 76 protein-altering or splice-affecting, 27 silent, 19 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 62, Silent 27, Intron 6, RNA 6, 3'UTR 5, Frame Shift Del 4, Nonsense Mutation 4, Frame Shift Ins 2, Splice Site 2, Splice Region 2, 5'UTR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MAX | c.83A>G p.H28R | Missense Mutation (SNP) | VAF 215/478 reads (45%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as COSV52415800; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 34/73 reads (47%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.388C>G p.R130G | Missense Mutation (SNP) | VAF 131/386 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- AMOTL2 | c.383C>T p.A128V | Missense Mutation (SNP) | VAF 14/390 reads (4%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs952660207; called by muse, mutect2
- ANKRD27 | c.2496C>T p.H832= | Splice Region (SNP) | VAF 10/90 reads (11%) | catalogued as rs750909575; called by muse, mutect2, varscan2
- ARHGEF7 | c.2555T>C p.M852T (on ENST00000646102 / NM_001354046.1; = p.M636T on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/203 reads (8%) | SIFT tolerated (0.89); PolyPhen benign (0.007); catalogued as rs1234012369; called by muse, mutect2
- BCL11B | c.1151G>A p.R384H (on ENST00000357195 / NM_001282237.2; = p.R313H on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1459432191; called by muse, mutect2, varscan2
- ETFB | c.265G>A p.V89M | Missense Mutation (SNP) | VAF 34/626 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs751703448, COSV58536177; called by muse, mutect2
- F2R | c.599G>A p.R200Q | Missense Mutation (SNP) | VAF 39/744 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59929977; called by muse, mutect2
- GABPB1 | c.1160G>A p.R387H | Missense Mutation (SNP) | VAF 54/215 reads (25%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.086); catalogued as rs986519244, COSV55014615; called by muse, mutect2, varscan2
- GLCCI1 | c.1294A>G p.M432V | Missense Mutation (SNP) | VAF 38/176 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.31); catalogued as rs1204711984, COSV56205180; called by muse, mutect2, varscan2
- GLI1 | c.1943G>A p.R648H | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs367789336, COSV57365774; called by muse, mutect2, varscan2
- GRIP2 | c.333C>T p.D111= (on ENST00000619221; = p.D14= on NM_001080423.4) | Splice Region (SNP) | VAF 74/455 reads (16%) | catalogued as rs369716360; called by muse, mutect2, varscan2
- GRM1 | c.340G>A p.V114M | Missense Mutation (SNP) | VAF 84/508 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51310207, COSV99266741; called by muse, mutect2, varscan2
- KLK15 | c.260G>A p.R87Q | Missense Mutation (SNP) | VAF 8/150 reads (5%) | SIFT tolerated (0.32); PolyPhen benign (0.119); catalogued as COSV56828942; called by muse, mutect2
- MYOCD | c.503G>T p.R168L | Missense Mutation (SNP) | VAF 62/303 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.039); catalogued as rs372928138; called by muse, mutect2, varscan2
- NDN | c.424C>T p.R142C | Missense Mutation (SNP) | VAF 10/272 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as COSV100086175, COSV59358609; called by muse, mutect2
- NR0B1 | c.370C>T p.R124W | Missense Mutation (SNP) | VAF 121/515 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.719); catalogued as COSV66764689; called by muse, mutect2, varscan2
- OR52N1 | c.593C>T p.A198V | Missense Mutation (SNP) | VAF 25/554 reads (5%) | SIFT tolerated (0.62); PolyPhen benign (0.1); catalogued as COSV100398714; called by muse, mutect2
- PCLO | c.6634G>C p.E2212Q | Missense Mutation (SNP) | VAF 24/151 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.361); catalogued as COSV100434755; called by muse, mutect2, varscan2
- PHEX | c.1141C>T p.R381C | Missense Mutation (SNP) | VAF 65/411 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs932260939, COSV65079335; called by muse, mutect2, varscan2
- PLEC | c.2486C>T p.T829M (on ENST00000322810 / NM_201380.4; = p.T719M on NM_000445.5) | Missense Mutation (SNP) | VAF 20/567 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs782213152; called by muse, mutect2
- PNPLA1 | c.56C>T p.S19L | Missense Mutation (SNP) | VAF 19/614 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1373230987; called by muse, mutect2
- PNPLA6 | c.2822T>G p.F941C (on ENST00000414982 / NM_001166111.2; = p.F893C on NM_006702.5) | Missense Mutation (SNP) | VAF 15/361 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99654717; called by muse, mutect2
- POLD1 | c.233G>A p.R78H | Missense Mutation (SNP) | VAF 54/200 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as rs750825686, COSV70956400; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PPM1D | c.203C>T p.P68L | Missense Mutation (SNP) | VAF 45/226 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs759311325; called by muse, mutect2, varscan2
- PPP1R37 | c.1168C>T p.R390C | Missense Mutation (SNP) | VAF 21/253 reads (8%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.792); catalogued as rs895090819, COSV55525135; called by muse, mutect2
- PTCH1 | c.4172G>A p.R1391Q | Missense Mutation (SNP) | VAF 24/348 reads (7%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as rs773676486, COSV59468772; ClinVar: likely benign / uncertain significance; called by muse, mutect2
- RRAS2 | c.473C>T p.A158V | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56332837; called by muse, mutect2, varscan2
- SCN11A | c.3337G>T p.G1113* | Nonsense Mutation (SNP) | VAF 23/224 reads (10%) | catalogued as rs1445569526; called by muse, mutect2, varscan2
- SH3GL2 | c.494G>A p.R165H | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV101014627; called by muse, mutect2
- SLC24A2 | c.988C>T p.R330* | Nonsense Mutation (SNP) | VAF 25/535 reads (5%) | catalogued as rs1444111756, COSV53864672; called by muse, mutect2
- SOS2 | c.3151A>G p.T1051A | Missense Mutation (SNP) | VAF 22/202 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.119); catalogued as rs764908956, COSV53574116; called by muse, mutect2, varscan2
- TRAM1L1 | c.1021T>G p.S341A | Missense Mutation (SNP) | VAF 38/150 reads (25%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as COSV100162408, COSV60291092; called by muse, mutect2, varscan2
- TTN | c.47968G>A p.V15990I (on ENST00000591111; = p.V8566I on NM_003319.4) | Missense Mutation (SNP) | VAF 34/558 reads (6%) | PolyPhen probably damaging (0.991); catalogued as rs749503285, COSV60285636; ClinVar: not provided / uncertain significance; called by muse, mutect2
- ZAN | c.5407C>T p.R1803W | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs534817290, COSV61815061; called by muse, mutect2
- ZCCHC7 | c.1281A>G p.I427M | Missense Mutation (SNP) | VAF 55/252 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs898084633; called by muse, mutect2, varscan2
- ABCA3 | c.4164+1G>A p.X1388_splice | Splice Site (SNP) | VAF 30/624 reads (5%) | called by muse, mutect2
- ABI1 | c.1111C>T p.Q371* | Nonsense Mutation (SNP) | VAF 27/165 reads (16%) | called by muse, mutect2, varscan2
- AJAP1 | c.326C>T p.A109V | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.01); called by muse, mutect2
- ALOXE3 | c.223G>A p.A75T | Missense Mutation (SNP) | VAF 104/433 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- ALX4 | c.935A>C p.N312T | Missense Mutation (SNP) | VAF 5/91 reads (5%) | SIFT tolerated (0.47); PolyPhen benign (0.109); called by muse, mutect2
- ARID1A | c.3697dup p.Y1233Lfs*11 | Frame Shift Ins (INS) | VAF 17/61 reads (28%) | called by mutect2, pindel
- ARID5B | c.1317_1318dup p.G440Vfs*40 | Frame Shift Ins (INS) | VAF 47/184 reads (26%) | called by mutect2, pindel, varscan2
- BMP5 | c.68G>T p.G23V | Missense Mutation (SNP) | VAF 63/235 reads (27%) | SIFT tolerated (0.48); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- C17orf50 | c.515G>A p.G172E | Missense Mutation (SNP) | VAF 13/357 reads (4%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.178); called by muse, mutect2
- CCDC148 | c.1214del p.K405Rfs*14 | Frame Shift Del (DEL) | VAF 32/148 reads (22%) | called by mutect2, pindel, varscan2
- CDK18 | c.1016C>T p.P339L (on ENST00000506784 / NM_212503.3; = p.P309L on NM_002596.4) | Missense Mutation (SNP) | VAF 66/355 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- CHD7 | c.1289T>C p.M430T | Missense Mutation (SNP) | VAF 9/154 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.006); called by muse, mutect2
- COL14A1 | c.3557C>T p.A1186V | Missense Mutation (SNP) | VAF 14/448 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.037); called by muse, mutect2
- DDX47 | c.339del p.A114Pfs*12 | Frame Shift Del (DEL) | VAF 90/476 reads (19%) | called by mutect2, pindel, varscan2
- DNAH10 | c.12986A>G p.N4329S (on ENST00000409039; = p.N4268S on NM_207437.3) | Missense Mutation (SNP) | VAF 25/183 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DNAJC13 | c.509G>A p.C170Y | Missense Mutation (SNP) | VAF 5/87 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); called by muse, mutect2
- EMILIN1 | c.1361C>T p.A454V | Missense Mutation (SNP) | VAF 4/76 reads (5%) | SIFT tolerated (0.26); PolyPhen benign (0.301); called by muse, mutect2
- FLNB | c.2972G>A p.C991Y | Missense Mutation (SNP) | VAF 25/508 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); called by muse, mutect2
- GRIA1 | c.284A>C p.N95T | Missense Mutation (SNP) | VAF 17/434 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.79); called by muse, mutect2
- IL18R1 | c.303-2A>G p.X101_splice | Splice Site (SNP) | VAF 4/36 reads (11%) | called by mutect2, varscan2
- IRAK3 | c.1054T>C p.S352P | Missense Mutation (SNP) | VAF 51/183 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- ITGA11 | c.1499T>C p.V500A | Missense Mutation (SNP) | VAF 13/381 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- ITGB5 | c.938A>G p.Q313R | Missense Mutation (SNP) | VAF 13/208 reads (6%) | SIFT tolerated (0.35); PolyPhen benign (0.009); called by muse, mutect2
- KCNT1 | c.3253C>T p.Q1085* (on ENST00000488444; = p.Q1111* on NM_020822.3) | Nonsense Mutation (SNP) | VAF 23/630 reads (4%) | called by muse, mutect2
- MYO16 | c.3514A>T p.S1172C | Missense Mutation (SNP) | VAF 50/286 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.72); called by muse, mutect2, varscan2
- NDUFB10 | c.144_157del p.H50Vfs*16 | Frame Shift Del (DEL) | VAF 30/176 reads (17%) | called by mutect2, pindel, varscan2
- OBSCN | c.21623C>T p.P7208L | Missense Mutation (SNP) | VAF 14/434 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- OR2J2 | c.870C>G p.I290M | Missense Mutation (SNP) | VAF 22/135 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PMPCA | c.1544G>T p.G515V | Missense Mutation (SNP) | VAF 9/210 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2
- PPRC1 | c.1406C>T p.A469V | Missense Mutation (SNP) | VAF 13/313 reads (4%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.003); called by muse, mutect2
- RAD21 | c.1063C>T p.P355S | Missense Mutation (SNP) | VAF 16/386 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- RRAGA | c.629C>T p.T210I | Missense Mutation (SNP) | VAF 15/398 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SIX4 | c.1900A>G p.N634D | Missense Mutation (SNP) | VAF 8/168 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.054); called by muse, mutect2
- SLC22A13 | c.394G>T p.D132Y | Missense Mutation (SNP) | VAF 55/214 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- TFAP2C | c.452C>A p.P151H | Missense Mutation (SNP) | VAF 12/175 reads (7%) | SIFT tolerated (0.92); PolyPhen probably damaging (0.91); called by muse, mutect2
- TJP1 | c.1306C>T p.R436W | Missense Mutation (SNP) | VAF 11/279 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TMEM121B | c.1103G>A p.R368Q | Missense Mutation (SNP) | VAF 26/452 reads (6%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.947); called by muse, mutect2
- TTC5 | c.325_335del p.L109Vfs*40 | Frame Shift Del (DEL) | VAF 41/299 reads (14%) | called by mutect2, pindel, varscan2
- ZNF467 | c.1409C>T p.S470L | Missense Mutation (SNP) | VAF 12/201 reads (6%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.695); called by muse, mutect2
- ABCA3 | c.1542C>A p.L514= | Silent (SNP) | VAF 186/621 reads (30%) | called by muse, mutect2, varscan2
- ABCC8 | c.297C>T p.T99= | Silent (SNP) | VAF 68/448 reads (15%) | called by muse, mutect2, varscan2
- CARMIL2 | c.4053G>A p.P1351= | Silent (SNP) | VAF 22/239 reads (9%) | catalogued as rs758885666; called by muse, mutect2
- CRB2 | c.426C>A p.T142= | Silent (SNP) | VAF 17/215 reads (8%) | called by muse, mutect2
- DAB2IP | c.2292G>T p.P764= (on ENST00000408936; = p.P736= on NM_032552.3) | Silent (SNP) | VAF 50/170 reads (29%) | called by muse, mutect2, varscan2
- DOCK4 | c.2659C>T p.L887= | Silent (SNP) | VAF 10/196 reads (5%) | called by muse, mutect2
- EFCAB8 | c.2166C>T p.L722= | Silent (SNP) | VAF 90/610 reads (15%) | called by muse, mutect2, varscan2
- FAM166A | c.306C>T p.G102= | Silent (SNP) | VAF 8/188 reads (4%) | called by muse, mutect2
- FANCG | c.715C>T p.L239= | Silent (SNP) | VAF 32/709 reads (5%) | catalogued as rs1317642688; called by muse, mutect2
- FCGBP | c.9738T>C p.P3246= | Silent (SNP) | VAF 46/644 reads (7%) | called by muse, mutect2, varscan2
- HCN4 | c.3438C>T p.P1146= | Silent (SNP) | VAF 66/358 reads (18%) | catalogued as rs549872016; called by muse, mutect2, varscan2
- HSPA9 | c.393T>C p.P131= | Silent (SNP) | VAF 16/494 reads (3%) | called by muse, mutect2
- INPP5J | c.1257C>T p.S419= | Silent (SNP) | VAF 15/39 reads (38%) | catalogued as rs367650817, COSV58513715; called by mutect2, varscan2
- INTS7 | c.2808C>T p.S936= | Silent (SNP) | VAF 14/296 reads (5%) | catalogued as COSV65345133; called by muse, mutect2
- MGAM | c.1002G>A p.A334= | Silent (SNP) | VAF 43/235 reads (18%) | catalogued as rs782793080, COSV101527373, COSV101527664, COSV72073467; called by muse, mutect2, varscan2
- MMP25 | c.1362G>A p.L454= | Silent (SNP) | VAF 53/254 reads (21%) | catalogued as rs372066511; called by muse, mutect2, varscan2
- P4HA2 | c.270G>A p.V90= | Silent (SNP) | VAF 13/376 reads (3%) | called by muse, mutect2
- PKDREJ | c.6195C>A p.T2065= | Silent (SNP) | VAF 10/115 reads (9%) | called by muse, mutect2
- PRDM9 | c.2628C>T p.C876= | Silent (SNP) | VAF 18/516 reads (3%) | called by muse, mutect2
- PRRT4 | c.1200G>A p.A400= | Silent (SNP) | VAF 114/678 reads (17%) | called by muse, mutect2, varscan2
- PTPRD | c.1920C>T p.G640= | Silent (SNP) | VAF 10/288 reads (3%) | catalogued as rs1486107383; called by muse, mutect2
- RIMBP3B | c.4452G>A p.R1484= | Silent (SNP) | VAF 12/110 reads (11%) | called by mutect2, varscan2
- RNF213 | c.11685C>T p.L3895= | Silent (SNP) | VAF 98/588 reads (17%) | called by muse, mutect2, varscan2
- SLC10A3 | c.588C>T p.L196= | Silent (SNP) | VAF 10/222 reads (5%) | called by muse, mutect2
- STK10 | c.2757G>A p.P919= | Silent (SNP) | VAF 9/229 reads (4%) | catalogued as rs1238071413; called by muse, mutect2
- TMED6 | c.27G>T p.G9= | Silent (SNP) | VAF 8/190 reads (4%) | called by muse, mutect2
- ZIC5 | c.1257G>A p.P419= | Silent (SNP) | VAF 10/125 reads (8%) | catalogued as rs529577435, COSV57438611; called by muse, mutect2
- AC002378.1 | n.112C>A | RNA (SNP) | VAF 12/196 reads (6%) | called by muse, mutect2
- AK2 | c.*320C>T | 3'UTR (SNP) | VAF 6/126 reads (5%) | called by muse, mutect2
- CORO1A | c.1007+23C>T | Intron (SNP) | VAF 26/568 reads (5%) | catalogued as rs747604475; called by muse, mutect2
- CSF3R | c.-21G>T | 5'UTR (SNP) | VAF 30/576 reads (5%) | called by muse, mutect2
- CTAGE11P | n.7G>T | RNA (SNP) | VAF 33/807 reads (4%) | called by muse, mutect2
- DENND10P1 | n.712T>C | RNA (SNP) | VAF 22/578 reads (4%) | called by muse, mutect2
- FBLN7 | c.670+53C>T | Intron (SNP) | VAF 12/214 reads (6%) | catalogued as rs1332905493, COSV99734891; called by muse, mutect2
- GABRE | c.784+824C>T | Intron (SNP) | VAF 6/122 reads (5%) | called by muse, mutect2
- HLA-V | n.108A>G | RNA (SNP) | VAF 22/94 reads (23%) | called by muse, mutect2, varscan2
- JPH3 | chr16:87701769 A>G | 3'Flank (SNP) | VAF 17/274 reads (6%) | called by muse, mutect2
- KCTD1 | c.-15-46255G>A | Intron (SNP) | VAF 47/220 reads (21%) | catalogued as rs1391190899; called by muse, mutect2, varscan2
- MIR325 | n.55T>C | RNA (SNP) | VAF 28/136 reads (21%) | called by muse, mutect2, varscan2
- NTHL1 | c.*33_*56del | 3'UTR (DEL) | VAF 70/303 reads (23%) | called by mutect2, pindel, varscan2
- PEG10 | c.*1121G>A | 3'UTR (SNP) | VAF 8/102 reads (8%) | called by muse, mutect2
- PEX19 | c.*1722A>G | 3'UTR (SNP) | VAF 17/636 reads (3%) | called by muse, mutect2
- RUNX1 | c.532+3130G>A | Intron (SNP) | VAF 43/325 reads (13%) | called by muse, mutect2, varscan2
- SAR1B | c.*44C>T | 3'UTR (SNP) | VAF 60/246 reads (24%) | catalogued as rs774221749; called by muse, mutect2, varscan2
- SPATA31C1 | n.2713G>A | RNA (SNP) | VAF 26/622 reads (4%) | called by muse, mutect2
- TSSC2 | n.288-5473T>C | Intron (SNP) | VAF 18/510 reads (4%) | called by muse, mutect2
